Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9UL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9UL-01A (Primary Tumor).

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

"Uterine cervix biopsy":

Squamous cell carcinoma, histologic grade 3, invasive, with necrotic areas.

ICD-O.3

Carcinoma, squamous cell NOS 8070/3
Site: Cervix NOS C53.9

9/3/14

Source: NCI Genomic Data Commons file 7d505eb0-b2fb-452f-8512-613d70c954a5 (TCGA-VS-A9UL.79869158-C990-45B6-B77B-A6CEC4886E5C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).